Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H0-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

CASE NUMBER:

DIAGNOSIS:

Final Results

Final

1. Soft, paraganglioma, frozen section (1FS):
- * Paranganglioma
- * Inked margins free of tumor
- * Nerve and ganglion present

2. Rib, 2nd right, resection: Gross only

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: history of sdhb mutation, right sided
paranganglioma on T1 Specimen Taken For Protocol: - Yes Allocate
Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: history of sdhb mutation, right sided
paranganglioma Post-Operative Diagnosis: history of sdhb mutation, right sided paranganglioma Operative Findings: mass on right T1, adjacent to right innominate

SPECIMENS SUBMITTED: 1. SOFT TISSUE, NOS, Paranganglioma (1FS)
2. RIB, Right 2nd

INTRAOPERATIVE CONSULTATION:

1FS "Paranganglioma"
- 1FSDX: Neuroendocrine tumor, consistent with paranganglioma.
Representative margin face of tumor.

Frozen section diagnosis was performed by

GROSS DESCRIPTION:

1. Received fresh from the OR is a specimen labeled with the patient's name, MRN and further specified as "paranganglioma" consists of a red to membrane-covered wedge resection specimen with associated staple line

Requested By:

Do not file in Medical Record

[page 2 of 2]
measuring 6.2 x 3.0 x 2.5 cm. The staple line measures 5.0 cm. Per Dr.

the deep margin was inked in black in the OR. There is a palpable nodule (approximately 2.5 x 1.0 cm) just beneath the deep margin. The inked deep margin is removed revealing a circumscribed nodule measuring 3.0 x 2.0 cm. Cut surface is brown, tan and lobulated. A representative section of the tumor at close proximity to the deep margin is frozen as 1FS. Fifty percent of the tumor is procured for Dr.

The specimen is received in Surgical Pathology and matches the above description. The frozen section specimen is wrapped in lens paper and placed in a green cassette, submitted to formalin to Surgical Pathology. The specimen is received in Surgical Pathology and matches the above description. The frozen section specimen is transferred to an orange cassette labeled 1FS for permanent processing. The remainder of the specimen is bisected with one-half of the specimen consisting of the inked resection margin. The inked resection margin is serially sectioned and submitted in cassettes 1A-1C. Representative sections of the remaining specimen including normal appearing lung are submitted in cassettes 1D-1F for permanent processing.

2. Received in a formalin-filled container labeled with the patient's name, MRN, date of birth and further specified as "right rib #2" is a partial rib resection specimen measuring 7.5 x 2.9 x 1.0 cm overall with attached intercostal muscle measuring 1 x 0.6 x 0.7 cm. No gross lesions are noted. The specimen is gross only.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Requested By:

Do not file in Medical Record

IIA/IIIA Discrepancy		/
Major Malignancy History		/

Source: NCI Genomic Data Commons file 486fdecd-b13b-4779-9596-d30750e78068 (TCGA-QR-A6H0.25844561-A084-4F60-ACAF-69C5DD2A1525.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).